Gene-level copy-number profile of tumor specimen ALCH-AE9A-TTP1-A from ALCHEMIST case ALCH-AE9A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.5 years (25,391 days).
Specimen ALCH-AE9A-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 65413ee1-280f-409d-bb18-04a192391ead.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE9A-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,384 have no estimate.
https://portal.gdc.cancer.gov/files/0a793f48-c4cf-4167-8ba6-bef26b9070e2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 27; copy number 2: 854; copy number 3: 31,652; copy number 4: 24,335; copy number 5: 1,085; copy number 6: 196; copy number 7: 48; copy number 8: 6; copy number 9: 8; copy number 10: 6; copy number 11: 6; copy number 14: 1; copy number 29: 3; copy number 37: 2; copy number 47: 8.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:139,367,196–139,384,553, 1 gene (within-gene range 0–3): SLC23A1.
- chr14:101,948,347–101,949,425, 1 gene: AL118558.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 88 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,203,508–1,206,592, 1 gene, copy number 7: TNFRSF18.
- chr1:2,425,980–2,526,597, 4 genes, copy number 8–11: PLCH2, AL139246.1, AL139246.4, PANK4.
- chr5:38,460,925–38,468,339, 1 gene, copy number 7 (within-gene range 5–7): AC010457.1.
- chr8:7,238,286–7,298,024, 8 genes, copy number 47: AF228730.3, OR7E125P, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P, FAM90A20P.
- chr8:102,805,517–102,810,039, 1 gene, copy number 7: GASAL1.
- chr8:141,514,638–141,518,737, 1 gene, copy number 7: AC138647.1.
- chr8:142,620,373–142,640,648, 2 genes, copy number 7–10: AP006547.1, AC108002.2.
- chr8:142,750,150–142,752,532, 1 gene, copy number 9: LYPD2.
- chr11:2,129,112–2,173,138, 9 genes, copy number 7: IGF2, AC132217.2, AC132217.1, INS-IGF2, MIR483, IGF2-AS, INS, TH, MIR4686.
- chr12:131,478,844–131,483,034, 1 gene, copy number 7: AC073578.3.
- chr14:36,657,568–36,679,362, 1 gene, copy number 7 (within-gene range 4–7): PAX9.
- chr14:44,763,153–44,782,829, 1 gene, copy number 7: LINC02302.
- chr14:45,567,995–45,569,069, 1 gene, copy number 7: AL139354.1.
- chr14:49,057,713–49,077,505, 1 gene, copy number 7: AL110505.1.
- chr14:63,298,126–63,318,935, 2 genes, copy number 7: AL049871.1, GPHB5.
- chr14:63,543,569–63,544,664, 1 gene, copy number 7: AL136038.3.
- chr14:63,808,546–63,808,732, 1 gene, copy number 8: RPS28P1.
- chr16:991,151–1,000,926, 1 gene, copy number 10: AC009041.1.
- chr16:32,356,981–32,380,049, 2 genes, copy number 7: AC133548.1, ACTR3BP3.
- chr16:32,475,051–32,478,250, 1 gene, copy number 7: ABCD1P3.
- chr16:32,845,964–32,888,874, 5 genes, copy number 7–29: AC142086.2, IGHV2OR16-5, BCAP31P2, SLC6A10P, AC142086.1.
- chr16:33,043,609–33,095,431, 1 gene, copy number 7 (within-gene range 5–7): AC145350.2.
- chr16:33,094,204–33,570,935, 19 genes, copy number 7–10: HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr16:33,802,764–33,810,767, 2 genes, copy number 37: IGHV3OR16-12, AC136428.3.
- chr17:2,017,716–2,023,664, 2 genes, copy number 8 (within-gene range 3–8): AC099684.1, AC099684.3.
- chr19:34,923,299–34,926,812, 1 gene, copy number 7: ZNF30-AS1.
- chr20:63,528,001–63,556,695, 4 genes, copy number 7–11: PTK6, SRMS, AL121829.2, FNDC11.
- chr22:15,528,192–15,578,006, 6 genes, copy number 9: OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1.
- chr22:20,111,875–20,151,055, 4 genes, copy number 7–14 (within-gene range 1–14): TRMT2A, MIR6816, ZDHHC8, CCDC188.
- chr22:21,114,607–21,142,371, 3 genes, copy number 9–11 (within-gene range 6–11): AP000550.1, POM121L7P, E2F6P2.

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
